Somatic mutation profile of cancer-model specimen HCM-SANG-0277-C18-85A (3D Organoid; aliquot HCM-SANG-0277-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0277-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G3.
Specimen HCM-SANG-0277-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18cfe6b3-9066-46d2-8e00-92ccc49f9d83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0277-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0277-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e428d2ce-812f-4bea-b762-3f74ad378763

The open-access MAF lists 319 somatic variants for this specimen: 246 protein-altering or splice-affecting, 65 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 213, Silent 65, Nonsense Mutation 18, Frame Shift Ins 6, Frame Shift Del 5, Intron 2, 3'UTR 2, Splice Region 2, Nonstop Mutation 1, In Frame Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2995C>T p.Q999* | Nonsense Mutation (SNP) | VAF 92/213 reads (43%) | catalogued as rs75239284, CM994279, COSV57331655; ClinVar: pathogenic; called by muse, varscan2
- CPS1 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 101/203 reads (50%) | catalogued as rs121912596, CM071660, COSV99243584; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.361T>A p.C121S | Missense Mutation (SNP) | VAF 323/324 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1057519856, COSV100199074, COSV61068761; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 317/319 reads (99%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV56683948; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 91/193 reads (47%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- A2ML1 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 98/195 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as rs1041548414, COSV55285979; called by muse, mutect2, varscan2
- ABHD15 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 231/499 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs374284598, COSV56196215; called by muse, mutect2, varscan2
- ACTN2 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 115/396 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs780552939, COSV100857076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS7 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 251/430 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as rs765564823; called by muse, mutect2, varscan2
- ALKAL2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.554); catalogued as rs748374754, COSV60417030; called by muse, mutect2, varscan2
- ALKBH8 | c.215A>T p.D72V | Missense Mutation (SNP) | VAF 115/351 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs566527389, COSV52835784; called by muse, mutect2, varscan2
- ANK3 | c.2980G>T p.G994W (on ENST00000280772 / NM_001320874.2; = p.G128W on NM_001149.3) | Missense Mutation (SNP) | VAF 166/322 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55055058; called by muse, mutect2, varscan2
- AP4M1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 314/458 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as rs757649099, COSV57999393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.4364del p.N1455Ifs*18 | Frame Shift Del (DEL) | VAF 129/345 reads (37%) | catalogued as CM080064, COSV57320740, COSV57379025; called by mutect2, pindel, varscan2
- ARMC4 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 189/332 reads (57%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs749707046; called by muse, mutect2, varscan2
- ATP10A | c.2200T>G p.F734V | Missense Mutation (SNP) | VAF 66/489 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV63525890; called by muse, mutect2, varscan2
- BDNF | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 51/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339220115, COSV59234219; called by muse, mutect2, varscan2
- BMP2K | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs773269909, COSV100621820; called by muse, varscan2
- BUB1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 105/357 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as rs375036331; ClinVar: likely benign; called by muse, mutect2, varscan2
- CADM2 | c.196T>G p.F66V (on ENST00000407528 / NM_001167674.2; = p.F68V on NM_153184.4) | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67409327; called by muse, mutect2
- CCDC169 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 173/353 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs1289400696, COSV53484524; called by muse, mutect2, varscan2
- CDH18 | c.785A>C p.N262T | Missense Mutation (SNP) | VAF 69/285 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs760356902; called by muse, mutect2, varscan2
- CELSR1 | c.5263G>A p.G1755S | Missense Mutation (SNP) | VAF 146/328 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs745985122, COSV53087180, COSV53098535; called by muse, mutect2, varscan2
- COL4A5 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs747334587; called by muse, mutect2, varscan2
- CPA4 | c.145T>G p.L49V | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs753729888; called by muse, mutect2, varscan2
- CSMD1 | c.748T>G p.F250V | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV101227380; called by muse, mutect2, varscan2
- CTNS | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 152/281 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as rs555311279, COSV50439978; called by muse, mutect2, varscan2
- CYP4F3 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs753746588, COSV55408314; called by muse, mutect2
- DACH2 | c.1757A>C p.N586T | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as COSV64165353; called by muse, mutect2, varscan2
- DIO3 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 229/427 reads (54%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs554569043, COSV63773161; called by muse, mutect2, varscan2
- DOCK3 | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 207/398 reads (52%) | catalogued as rs1030780615, COSV56553006; called by muse, mutect2, varscan2
- DOK6 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 157/352 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs1055076812, COSV66938476; called by muse, mutect2, varscan2
- DSG4 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 141/276 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs776703259, COSV57391097; called by muse, mutect2, varscan2
- EFHC1 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 208/457 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs769799699; called by muse, mutect2, varscan2
- EPPK1 | c.3700G>A p.E1234K | Missense Mutation (SNP) | VAF 275/541 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs782782070, COSV101599708; called by muse, mutect2, varscan2
- ERBB3 | c.2000G>T p.R667L | Missense Mutation (SNP) | VAF 174/376 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57247278, COSV57260257; called by muse, mutect2, varscan2
- EVC2 | c.2553G>A p.M851I | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs545949431, COSV60388325; called by muse, mutect2, varscan2
- EVC2 | c.1349A>C p.K450T | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100185266; called by muse, mutect2, varscan2
- FAT4 | c.13482T>G p.S4494R | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.203); catalogued as COSV58686830; called by muse, mutect2
- FCRL4 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 114/221 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs557969488, COSV54859731; called by muse, mutect2, varscan2
- FERD3L | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 511/810 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs768552326, COSV99285195; called by muse, mutect2, varscan2
- FOXC2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 175/454 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs1190156347, COSV100234306; called by muse, mutect2, varscan2
- FPR2 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 195/672 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs367971570; called by muse, mutect2, varscan2
- FSD1 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 136/273 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55695912; called by muse, mutect2, varscan2
- FST | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 111/213 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs201163221; called by muse, mutect2, varscan2
- GPR174 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 208/208 reads (100%) | catalogued as rs753195995, COSV99338073; called by muse, mutect2, varscan2
- GRIN2A | c.1983A>C p.Q661H | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58022707; called by muse, mutect2
- GRIN2B | c.3508G>A p.G1170R | Missense Mutation (SNP) | VAF 75/543 reads (14%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.049); catalogued as COSV101663237; called by muse, mutect2
- GRM5 | c.3356C>T p.P1119L (on ENST00000305447 / NM_001143831.2; = p.P1087L on NM_000842.4) | Missense Mutation (SNP) | VAF 269/513 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59595895, COSV59618119; called by muse, varscan2
- HELZ2 | c.4450G>A p.A1484T (on ENST00000467148 / NM_001037335.2; = p.A915T on NM_033405.3) | Missense Mutation (SNP) | VAF 29/630 reads (5%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.742); catalogued as rs1222324177; called by muse, mutect2
- HK3 | c.976T>G p.L326V | Missense Mutation (SNP) | VAF 67/489 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV99459770; called by muse, mutect2, varscan2
- HRH4 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 125/267 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs149820026; called by muse, mutect2, varscan2
- HS3ST3A1 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 154/595 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1300016001; called by muse, mutect2, varscan2
- HS3ST3B1 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100714485; called by mutect2, varscan2
- HSPG2 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 198/360 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs780963482, COSV65930185; called by muse, mutect2, varscan2
- IGKV1D-43 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 134/355 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs1415167798; called by muse, mutect2, varscan2
- IRAG2 | c.3926C>G p.S1309* (on ENST00000636465; = p.S354* on NM_006152.4 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/236 reads (10%) | catalogued as COSV57229919; called by muse, mutect2
- KCNQ2 | c.1657C>T p.R553W (on ENST00000359125 / NM_172107.4; = p.R525W on NM_004518.6) | Missense Mutation (SNP) | VAF 126/273 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759584387, CM136425; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KLHL10 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 206/400 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs782626896; called by muse, mutect2, varscan2
- LOXL4 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 286/590 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1459020336; called by muse, mutect2, varscan2
- MAP2K3 | c.743A>C p.K248T (on ENST00000342679 / NM_145109.3; = p.K219T on NM_002756.4) | Missense Mutation (SNP) | VAF 32/648 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1229469947; called by muse, mutect2
- MATN4 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 122/409 reads (30%) | PolyPhen possibly damaging (0.591); catalogued as rs1278672974, COSV100637104; called by muse, mutect2, varscan2
- MKS1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 142/314 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs775558298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 195/444 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs746758304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs774090650, COSV59124937, COSV59152211; called by muse, mutect2, varscan2
- MYO9A | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1297349712, COSV61853222; called by muse, mutect2
- NBEA | c.4965A>C p.K1655N | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.056); catalogued as COSV100075386; called by muse, mutect2, varscan2
- NCOA3 | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100507397; called by muse, mutect2, varscan2
- NEB | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376835458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NME8 | c.507dup p.V170Sfs*5 | Frame Shift Ins (INS) | VAF 38/165 reads (23%) | catalogued as rs1167912395; called by mutect2, pindel, varscan2
- NTRK1 | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 227/453 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763940977; called by muse, mutect2, varscan2
- OR2L3 | c.662T>C p.L221P | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1257946024; called by muse, varscan2
- OR6Y1 | c.899A>G p.H300R | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1200239720; called by muse, mutect2, varscan2
- PCDHA8 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 245/522 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); catalogued as rs782601520, COSV65329548, COSV65330942; called by muse, mutect2, varscan2
- PCDHB3 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 26/806 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV50564466; called by muse, mutect2
- PCDHB5 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 190/674 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as COSV50647224; called by muse, mutect2, varscan2
- PCDHGA5 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 69/455 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV54014928; called by muse, mutect2, varscan2
- PCDHGA5 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 113/382 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.021); catalogued as COSV53947180; called by muse, mutect2, varscan2
- PCDHGB4 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53961874; called by muse, mutect2
- PGLYRP1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 158/705 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.481); catalogued as rs573916071, COSV99151501; called by muse, mutect2, varscan2
- PIK3CB | c.1661A>G p.E554G | Missense Mutation (SNP) | VAF 274/278 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56689383; called by muse, mutect2, varscan2
- PKHD1 | c.9824T>G p.L3275R | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100582291, COSV61862672; called by muse, mutect2, varscan2
- PLPPR4 | c.1561A>G p.R521G | Missense Mutation (SNP) | VAF 54/359 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64564975, COSV64566071; called by muse, mutect2, varscan2
- PLXNA3 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs782372293; called by muse, mutect2, varscan2
- PPARGC1A | c.796T>G p.S266A | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs1179948708; called by muse, mutect2
- PPP1R3A | c.1129A>G p.S377G | Missense Mutation (SNP) | VAF 85/432 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV52888854; called by muse, mutect2, varscan2
- PRAMEF8 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 75/534 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1435289031; called by muse, mutect2, varscan2
- PRDM13 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 28/587 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1374293085; called by muse, mutect2
- PRR5-ARHGAP8 | c.1249G>A p.E417K (on ENST00000352766; = p.E338K on NM_181334.5) | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as rs540915857, COSV61231879; called by muse, mutect2, varscan2
- PSMD3 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 36/520 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs776745025, COSV52859713; called by muse, mutect2
- PTX3 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs750633744; called by muse, mutect2, varscan2
- RASGRF2 | c.1841C>A p.S614Y | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54139592; called by muse, mutect2, varscan2
- RBM22 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 111/353 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs755478465, COSV52271067; called by muse, mutect2, varscan2
- RFLNB | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs782557368; called by muse, mutect2, varscan2
- RGS11 | c.940C>T p.R314W (on ENST00000397770 / NM_183337.3; = p.R293W on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/343 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747085732, COSV51452388; called by muse, mutect2, varscan2
- RMND5B | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs574041577; called by muse, mutect2, varscan2
- RNFT2 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 172/329 reads (52%) | catalogued as rs752308240; called by muse, mutect2, varscan2
- ROBO2 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs763833545, COSV59905182; called by muse, varscan2
- RYR1 | c.5171G>A p.R1724H | Missense Mutation (SNP) | VAF 292/1141 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as rs372800648; called by muse, mutect2, varscan2
- SGCZ | c.694T>C p.F232L | Missense Mutation (SNP) | VAF 100/278 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV101172137, COSV66016847; called by muse, mutect2, varscan2
- SH3BP5 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 195/404 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as rs772857315; called by muse, mutect2, varscan2
- SHOC1 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs889292600, COSV100598079; called by muse, mutect2, varscan2
- SHPK | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 226/468 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772517886; called by muse, mutect2, varscan2
- SKIV2L | c.3605G>A p.R1202H | Missense Mutation (SNP) | VAF 228/644 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368453711; called by muse, mutect2, varscan2
- SLC12A6 | c.1429G>A p.V477I (on ENST00000354181 / NM_001365088.1; = p.V426I on NM_005135.2) | Missense Mutation (SNP) | VAF 15/349 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.456); catalogued as rs931807370; called by muse, mutect2
- SNED1 | c.2065G>A p.G689R | Missense Mutation (SNP) | VAF 58/416 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs565535804; called by muse, mutect2, varscan2
- SORCS3 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 128/307 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs550554404, COSV63804214; called by muse, mutect2, varscan2
- SPG11 | c.3532C>T p.H1178Y | Missense Mutation (SNP) | VAF 104/209 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs1396440197; called by muse, mutect2, varscan2
- TRANK1 | c.7813C>T p.R2605W | Missense Mutation (SNP) | VAF 160/368 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs371549764; called by muse, varscan2
- TRIM49 | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61670608; called by muse, mutect2, varscan2
- TRIM58 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 121/254 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs755932300, COSV100824884, COSV63571084; called by muse, mutect2, varscan2
- TRIM67 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 129/288 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs759061291, COSV64157994; called by muse, mutect2, varscan2
- TRIML2 | c.650A>T p.K217M | Missense Mutation (SNP) | VAF 43/291 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV58719574; called by muse, mutect2, varscan2
- TRPS1 | c.112T>G p.S38A (on ENST00000220888 / NM_001330599.2; = p.S51A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/408 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV55259131; called by muse, mutect2
- TTN | c.12250C>T p.R4084W (on ENST00000591111; = p.R4038W on NM_003319.4) | Missense Mutation (SNP) | VAF 183/367 reads (50%) | catalogued as rs1265208597, COSV59867986, COSV60391908; called by muse, mutect2, varscan2
- TTN | c.1799A>T p.K600M | Missense Mutation (SNP) | VAF 92/197 reads (47%) | PolyPhen benign (0.244); catalogued as rs750819553; called by muse, mutect2, varscan2
- UBE2J2 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 119/254 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV59573782; called by muse, mutect2, varscan2
- VSX1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 351/707 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs746221110; called by muse, mutect2, varscan2
- WIZ | c.4694C>T p.P1565L (on ENST00000673675 / NM_001371589.1; = p.P470L on NM_021241.3) | Missense Mutation (SNP) | VAF 194/563 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs750718700, COSV54604161; called by muse, mutect2, varscan2
- ZFP69 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 136/282 reads (48%) | catalogued as rs200916688; called by muse, mutect2, varscan2
- ZNF175 | c.610A>C p.S204R | Missense Mutation (SNP) | VAF 30/534 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99219729; called by muse, mutect2
- ZNF33A | c.1348C>T p.R450C (on ENST00000458705 / NM_006974.3; = p.R451C on NM_006954.2) | Missense Mutation (SNP) | VAF 163/356 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs374444658; called by muse, mutect2, varscan2
- ZNF461 | c.329A>T p.K110M | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV64453734, COSV64454333; called by muse, mutect2, varscan2
- ZNF569 | c.607A>G p.R203G | Missense Mutation (SNP) | VAF 20/620 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.3); catalogued as COSV57598914, COSV57599325; called by muse, mutect2
- ZNF613 | c.586C>T p.R196* (on ENST00000293471 / NM_001031721.4; = p.R160* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 134/594 reads (23%) | catalogued as rs752784535, COSV53271265; called by muse, mutect2, varscan2
- ZNF681 | c.704G>C p.C235S | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV101267476; called by muse, mutect2, varscan2
- ZNF780B | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 79/606 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756727716, COSV55467722; called by muse, mutect2, varscan2
- ZNF804A | c.1822A>T p.M608L | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100166443; called by muse, mutect2, varscan2
- ZNF813 | c.1689A>C p.K563N | Missense Mutation (SNP) | VAF 38/808 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1234501059, COSV67177336; called by muse, mutect2
- ZNF93 | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.182); catalogued as COSV100652171; called by muse, mutect2, varscan2
- ZSCAN18 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 219/923 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555800718, COSV53733122, COSV99559346; called by muse, mutect2, varscan2
- ABCA8 | c.2982T>G p.S994R | Missense Mutation (SNP) | VAF 26/307 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ADAMTS16 | c.734del p.K245Sfs*38 | Frame Shift Del (DEL) | VAF 117/293 reads (40%) | called by mutect2, pindel, varscan2
- ADAMTS3 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 102/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP12 | c.2602dup p.S868Kfs*12 | Frame Shift Ins (INS) | VAF 156/350 reads (45%) | called by mutect2, varscan2
- AMH | c.1676G>T p.C559F | Missense Mutation (SNP) | VAF 231/509 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD62 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 34/212 reads (16%) | called by muse, mutect2, varscan2
- ANKUB1 | c.1556T>G p.L519R | Missense Mutation (SNP) | VAF 12/327 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ANXA9 | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 196/397 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- C17orf97 | c.1016C>G p.P339R | Missense Mutation (SNP) | VAF 67/521 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.829); called by mutect2, varscan2
- CDH13 | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- CDH4 | c.2600T>C p.V867A | Missense Mutation (SNP) | VAF 22/642 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CERKL | c.1483G>T p.V495L (on ENST00000339098 / NM_001030311.2; = p.V469L on NM_201548.5) | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CHST8 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 94/1196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- CNTN4 | c.2599T>G p.L867V | Missense Mutation (SNP) | VAF 63/356 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CRACR2B | c.1045C>T p.R349W (on ENST00000525077 / NM_001286606.2; = p.A293V on NM_173584.4) | Missense Mutation (SNP) | VAF 220/469 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CTNND1 | c.2479C>T p.Q827* (on ENST00000399050 / NM_001085458.2; = p.Q821* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 105/206 reads (51%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.1239A>C p.Q413H | Missense Mutation (SNP) | VAF 102/333 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMBT1 | c.3266G>A p.G1089D (on ENST00000338354 / NM_001377530.1; = p.G590D on NM_004406.3) | Missense Mutation (SNP) | VAF 147/323 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.5251T>G p.Y1751D | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- E2F2 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 92/660 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FAM171A1 | c.1680A>T p.L560F | Missense Mutation (SNP) | VAF 19/468 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- FST | c.765dup p.C256Mfs*16 | Frame Shift Ins (INS) | VAF 158/374 reads (42%) | called by mutect2, pindel, varscan2
- GAS2L3 | c.1325_1326insA p.K443Qfs*22 | Frame Shift Ins (INS) | VAF 141/333 reads (42%) | called by mutect2, pindel, varscan2
- GDAP1L1 | c.170G>C p.S57T | Missense Mutation (SNP) | VAF 119/362 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GDF1 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 264/564 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); called by muse, varscan2
- GGN | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 342/1299 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR141 | c.172T>G p.L58V | Missense Mutation (SNP) | VAF 57/674 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GRM6 | c.723G>A p.G241= | Splice Region (SNP) | VAF 87/221 reads (39%) | called by muse, mutect2, varscan2
- GRM6 | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 147/480 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- H3C10 | c.112_114del p.K38del | In Frame Del (DEL) | VAF 152/290 reads (52%) | called by pindel, varscan2
- HPN | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 646/882 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- HTD2 | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- IFNA7 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 60/527 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- IVL | c.575A>C p.Q192P | Missense Mutation (SNP) | VAF 62/462 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by mutect2, varscan2
- KCNA10 | c.1304A>G p.K435R | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNH4 | c.1139G>A p.W380* | Nonsense Mutation (SNP) | VAF 197/416 reads (47%) | called by muse, mutect2, varscan2
- KIAA0895L | c.923T>A p.L308Q | Missense Mutation (SNP) | VAF 282/604 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF15 | c.3496G>A p.G1166R | Missense Mutation (SNP) | VAF 123/290 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF16B | c.1262A>C p.E421A | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- KLHL1 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 117/375 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- KMT2B | c.3805G>T p.E1269* | Nonsense Mutation (SNP) | VAF 574/772 reads (74%) | called by muse, mutect2, varscan2
- KRT34 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 66/367 reads (18%) | called by muse, mutect2, varscan2
- LAMA4 | c.2012_2013dup p.L672Tfs*32 (on ENST00000230538 / NM_001105206.3; = p.L665Tfs*32 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 43/345 reads (12%) | called by mutect2, pindel, varscan2
- LBH | c.194T>G p.V65G | Missense Mutation (SNP) | VAF 58/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC49 | c.1390A>C p.K464Q | Missense Mutation (SNP) | VAF 163/164 reads (99%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- MAGEA3 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.144); called by muse, mutect2
- MAP7D1 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 149/295 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MGAM2 | c.1918T>G p.F640V | Missense Mutation (SNP) | VAF 11/338 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2
- MLNR | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 204/381 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MSH5 | c.2231T>C p.V744A | Missense Mutation (SNP) | VAF 166/320 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MYH8 | c.3553A>G p.T1185A | Missense Mutation (SNP) | VAF 192/374 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NEMF | c.3197C>G p.S1066C | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NEURL1B | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NMUR2 | c.547A>T p.S183C | Missense Mutation (SNP) | VAF 52/403 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NPR1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NXF1 | c.849G>C p.M283I | Missense Mutation (SNP) | VAF 179/351 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR1J2 | c.845C>A p.T282K | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR2AT4 | c.49T>C p.Y17H | Missense Mutation (SNP) | VAF 49/401 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- OR2J2 | c.818A>C p.K273T | Missense Mutation (SNP) | VAF 49/438 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- OR2T8 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 57/520 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, varscan2
- OR5D16 | c.79A>C p.I27L | Missense Mutation (SNP) | VAF 20/407 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- OR9H1P | c.698A>G p.*233Wext*? | Nonstop Mutation (SNP) | VAF 40/380 reads (11%) | called by muse, mutect2
- OTUD7A | c.1189G>A p.D397N (on ENST00000307050 / NM_001382637.1; = p.D390N on NM_130901.3) | Missense Mutation (SNP) | VAF 53/377 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- P4HA2 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 134/269 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH15 | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB1 | c.1931T>G p.L644R | Missense Mutation (SNP) | VAF 70/423 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PCDHGA2 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 165/579 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCF11 | c.1194C>A p.N398K | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKIA | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHB1 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 159/319 reads (50%) | SIFT tolerated (0.98); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PPFIA1 | c.2023T>G p.F675V | Missense Mutation (SNP) | VAF 175/362 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.101); called by mutect2, varscan2
- PPFIA2 | c.2595A>T p.L865F | Missense Mutation (SNP) | VAF 116/237 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PRDM1 | c.437A>C p.H146P | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPN13 | c.1417T>G p.L473V | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBM39 | c.1181_1182del p.S394Ffs*14 | Frame Shift Del (DEL) | VAF 92/256 reads (36%) | called by pindel, varscan2
- RGL4 | c.1038A>C p.K346N | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); called by muse, mutect2
- RHOA | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- RLIM | c.1582T>G p.F528V | Missense Mutation (SNP) | VAF 171/267 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- RNF111 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 276/277 reads (100%) | called by muse, mutect2, varscan2
- RNF149 | c.236_246dup p.P83Sfs*80 | Frame Shift Ins (INS) | VAF 177/487 reads (36%) | called by mutect2, varscan2
- RNF152 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 211/432 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- SAC3D1 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 134/414 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SCN7A | c.1831C>G p.P611A | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- SETBP1 | c.3043T>A p.S1015T | Missense Mutation (SNP) | VAF 200/387 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SKIDA1 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 116/249 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SLC39A3 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 225/421 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SLC4A2 | c.1943C>G p.A648G | Missense Mutation (SNP) | VAF 336/533 reads (63%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A16 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 97/667 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMAD2 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 121/278 reads (44%) | called by muse, mutect2, varscan2
- SOX9 | c.1161_1173del p.E388Pfs*11 | Frame Shift Del (DEL) | VAF 199/461 reads (43%) | called by mutect2, pindel, varscan2
- ST8SIA6 | c.104T>G p.I35S | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- STRN | c.1673del p.P558Lfs*9 | Frame Shift Del (DEL) | VAF 93/230 reads (40%) | called by mutect2, pindel, varscan2
- SVEP1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 203/420 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- TBXA2R | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 308/560 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.055); called by muse, mutect2
- TG | c.6287T>G p.L2096R | Missense Mutation (SNP) | VAF 98/317 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TIMP3 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 152/302 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- TSPY1 | c.597C>A p.C199* | Nonsense Mutation (SNP) | VAF 115/722 reads (16%) | called by muse, mutect2, varscan2
- TTLL12 | c.1669G>T p.E557* | Nonsense Mutation (SNP) | VAF 172/375 reads (46%) | called by muse, mutect2, varscan2
- TTLL12 | c.840G>A p.Q280= | Splice Region (SNP) | VAF 14/463 reads (3%) | called by muse, mutect2
- UBR2 | c.2973G>T p.W991C | Missense Mutation (SNP) | VAF 100/204 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC79 | c.3287T>G p.F1096C (on ENST00000393151 / NM_001346218.2; = p.F919C on NM_020818.5) | Missense Mutation (SNP) | VAF 95/679 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- USP17L1 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 121/431 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- UTF1 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 213/486 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- WASF3 | c.1360C>A p.L454M | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY4 | c.3764T>G p.L1255R | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- XYLB | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 141/450 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZIK1 | c.162A>T p.E54D | Missense Mutation (SNP) | VAF 60/902 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF345 | c.834A>T p.R278S | Missense Mutation (SNP) | VAF 54/672 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF461 | c.920G>C p.G307A | Missense Mutation (SNP) | VAF 41/577 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- ZNF492 | c.647A>T p.K216M | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF608 | c.2111G>C p.G704A | Missense Mutation (SNP) | VAF 25/522 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF682 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 91/199 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF85 | c.1437G>C p.E479D | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZPLD1 | c.421A>G p.T141A (on ENST00000466937 / NM_001329788.1; = p.T157A on NM_175056.2) | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2
- ZSCAN5C | c.605T>C p.L202P | Missense Mutation (SNP) | VAF 111/516 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ADAD2 | c.741G>A p.P247= (on ENST00000315906 / NM_001145400.2; = p.P329= on NM_139174.4) | Silent (SNP) | VAF 190/432 reads (44%) | catalogued as rs374108586; called by muse, mutect2, varscan2
- ADAMTS16 | c.1779T>G p.S593= | Silent (SNP) | VAF 96/348 reads (28%) | catalogued as COSV56991849; called by muse, mutect2, varscan2
- ADARB2 | c.82C>A p.R28= | Silent (SNP) | VAF 42/415 reads (10%) | catalogued as rs1334103357, COSV67240031; called by muse, mutect2, varscan2
- BCORL1 | c.2424G>A p.T808= | Silent (SNP) | VAF 24/336 reads (7%) | catalogued as rs138691600, COSV54396533; called by muse, mutect2
- BNC2 | c.243C>T p.F81= | Silent (SNP) | VAF 175/372 reads (47%) | catalogued as rs754849003, COSV66140591; called by muse, mutect2, varscan2
- CDH10 | c.1569A>G p.K523= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as COSV52580120; called by muse, mutect2, varscan2
- CDH26 | c.1320C>T p.S440= | Silent (SNP) | VAF 42/332 reads (13%) | catalogued as rs747859766; called by muse, mutect2, varscan2
- CRB2 | c.576G>A p.P192= | Silent (SNP) | VAF 46/552 reads (8%) | catalogued as rs1040869162; called by muse, mutect2
- CSMD1 | c.3717T>G p.T1239= (on ENST00000520002; = p.T1238= on NM_033225.6) | Silent (SNP) | VAF 185/377 reads (49%) | catalogued as COSV59310134; called by muse, mutect2, varscan2
- CSMD3 | c.3045A>T p.I1015= (on ENST00000297405 / NM_001363185.1; = p.I911= on NM_052900.3) | Silent (SNP) | VAF 103/270 reads (38%) | called by muse, mutect2, varscan2
- DNAH5 | c.8004A>G p.G2668= | Silent (SNP) | VAF 78/155 reads (50%) | called by muse, mutect2, varscan2
- DSEL | c.3459C>T p.A1153= | Silent (SNP) | VAF 191/365 reads (52%) | called by muse, mutect2, varscan2
- FAM170B | c.651C>T p.D217= | Silent (SNP) | VAF 124/463 reads (27%) | catalogued as rs752452944; called by muse, mutect2, varscan2
- FAM20C | c.615G>A p.A205= | Silent (SNP) | VAF 195/598 reads (33%) | catalogued as rs767807372, COSV58233063; called by muse, mutect2, varscan2
- FLI1 | c.462C>T p.I154= | Silent (SNP) | VAF 187/368 reads (51%) | catalogued as rs745359490, COSV55644091; called by muse, mutect2, varscan2
- FMO1 | c.504C>G p.G168= | Silent (SNP) | VAF 45/159 reads (28%) | called by muse, varscan2
- FXYD5 | c.318G>A p.T106= | Silent (SNP) | VAF 642/838 reads (77%) | catalogued as rs373475541; called by muse, mutect2, varscan2
- GABBR1 | c.2877T>C p.L959= | Silent (SNP) | VAF 123/341 reads (36%) | called by muse, mutect2, varscan2
- GK3P | c.738G>A p.G246= | Silent (SNP) | VAF 185/399 reads (46%) | catalogued as rs756937320, COSV56983892; called by muse, mutect2, varscan2
- GNAO1 | c.450C>T p.N150= | Silent (SNP) | VAF 145/333 reads (44%) | catalogued as rs185369495; ClinVar: benign; called by muse, mutect2, varscan2
- GPR26 | c.189G>A p.T63= | Silent (SNP) | VAF 98/536 reads (18%) | catalogued as rs776487078, COSV52932599; called by muse, mutect2, varscan2
- HRNR | c.2001C>T p.S667= | Silent (SNP) | VAF 262/560 reads (47%) | catalogued as rs374849852; called by muse, mutect2, varscan2
- IL9R | c.1425T>C p.S475= | Silent (SNP) | VAF 24/444 reads (5%) | catalogued as rs1440441197; called by muse, mutect2
- JHY | c.1980C>T p.L660= | Silent (SNP) | VAF 76/188 reads (40%) | catalogued as rs1340407392, COSV57077891, COSV57079963; called by muse, mutect2, varscan2
- KATNIP | c.1323C>T p.V441= | Silent (SNP) | VAF 33/294 reads (11%) | catalogued as rs764292995, COSV55179957; called by muse, mutect2, varscan2
- KCNH5 | c.1332G>C p.V444= | Silent (SNP) | VAF 17/272 reads (6%) | called by muse, mutect2
- KLF7 | c.60C>A p.G20= | Silent (SNP) | VAF 171/382 reads (45%) | called by muse, mutect2, varscan2
- KLHL20 | c.282A>G p.R94= | Silent (SNP) | VAF 54/348 reads (16%) | called by muse, mutect2, varscan2
- LCE6A | c.162T>A p.P54= | Silent (SNP) | VAF 141/283 reads (50%) | called by muse, mutect2, varscan2
- LCN6 | c.279C>T p.S93= | Silent (SNP) | VAF 183/384 reads (48%) | catalogued as rs148747287; called by muse, mutect2, varscan2
- LRRC4B | c.1905G>A p.A635= | Silent (SNP) | VAF 111/1456 reads (8%) | catalogued as rs767664857; called by muse, mutect2
- MROH9 | c.2523A>G p.S841= | Silent (SNP) | VAF 63/194 reads (32%) | called by muse, mutect2, varscan2
- NIPBL | c.2856G>A p.A952= | Silent (SNP) | VAF 40/229 reads (17%) | catalogued as rs371566938; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUDT6 | c.678C>T p.I226= | Silent (SNP) | VAF 164/373 reads (44%) | called by muse, mutect2, varscan2
- OBSL1 | c.4023C>T p.C1341= | Silent (SNP) | VAF 225/461 reads (49%) | catalogued as rs749717075, COSV54708751; ClinVar: uncertain significance; called by muse, varscan2
- OR2M7 | c.391A>C p.R131= | Silent (SNP) | VAF 64/352 reads (18%) | catalogued as COSV100522763; called by muse, mutect2, varscan2
- OR2T33 | c.337T>C p.L113= | Silent (SNP) | VAF 160/968 reads (17%) | called by muse, mutect2
- OR4A8 | c.675T>G p.T225= | Silent (SNP) | VAF 10/309 reads (3%) | called by muse, mutect2
- OR4K2 | c.745T>C p.L249= | Silent (SNP) | VAF 63/402 reads (16%) | called by muse, mutect2, varscan2
- PAX6 | c.420C>T p.D140= | Silent (SNP) | VAF 198/385 reads (51%) | catalogued as rs1800427; called by muse, mutect2, varscan2
- PCDHA13 | c.2229C>T p.S743= | Silent (SNP) | VAF 193/390 reads (49%) | catalogued as COSV56494255; called by muse, mutect2, varscan2
- PCDHGA5 | c.990C>T p.S330= | Silent (SNP) | VAF 191/397 reads (48%) | catalogued as COSV54049695; called by muse, mutect2, varscan2
- PDE1C | c.762G>A p.T254= | Silent (SNP) | VAF 39/282 reads (14%) | catalogued as rs180868654; called by muse, mutect2, varscan2
- PDGFB | c.366G>A p.P122= | Silent (SNP) | VAF 249/513 reads (49%) | catalogued as rs772178312; called by muse, mutect2, varscan2
- PEG3 | c.651T>A p.A217= | Silent (SNP) | VAF 62/718 reads (9%) | called by muse, mutect2
- POLB | c.810C>A p.L270= | Silent (SNP) | VAF 65/186 reads (35%) | called by muse, mutect2, varscan2
- POU4F1 | c.999C>T p.L333= | Silent (SNP) | VAF 214/444 reads (48%) | catalogued as rs200023415, COSV65884467, COSV65884714, COSV65885282; called by muse, mutect2, varscan2
- PTPRN2 | c.603G>A p.A201= | Silent (SNP) | VAF 208/596 reads (35%) | catalogued as rs369320878; called by muse, mutect2
- RAB33A | c.81G>A p.S27= | Silent (SNP) | VAF 15/310 reads (5%) | catalogued as COSV57061616; called by muse, mutect2
- RECQL4 | c.288G>A p.R96= | Silent (SNP) | VAF 30/728 reads (4%) | called by muse, mutect2
- SIGLEC5 | c.612C>T p.P204= | Silent (SNP) | VAF 252/1016 reads (25%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.429G>A p.T143= | Silent (SNP) | VAF 100/188 reads (53%) | catalogued as rs1486008663; called by muse, mutect2, varscan2
- SLF1 | c.81T>G p.L27= | Silent (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- SLITRK4 | c.531C>T p.F177= | Silent (SNP) | VAF 175/177 reads (99%) | catalogued as rs143940780, COSV62022415; called by muse, mutect2, varscan2
- SPACA9 | c.324C>T p.N108= | Silent (SNP) | VAF 30/301 reads (10%) | catalogued as rs746012729; called by muse, mutect2
- STX19 | c.807A>G p.G269= | Silent (SNP) | VAF 105/199 reads (53%) | called by muse, mutect2, varscan2
- TCEAL6 | c.400C>T p.L134= | Silent (SNP) | VAF 30/350 reads (9%) | called by muse, mutect2
- THBD | c.1095C>T p.P365= | Silent (SNP) | VAF 164/513 reads (32%) | called by muse, mutect2, varscan2
- TSC2 | c.669C>T p.D223= | Silent (SNP) | VAF 136/289 reads (47%) | catalogued as rs35501344; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- TUBB4A | c.1281C>T p.D427= | Silent (SNP) | VAF 212/433 reads (49%) | catalogued as rs149205820; called by muse, mutect2, varscan2
- ZNF256 | c.870T>G p.T290= | Silent (SNP) | VAF 24/884 reads (3%) | called by muse, mutect2
- ZNF430 | c.303G>A p.A101= | Silent (SNP) | VAF 102/240 reads (43%) | catalogued as rs147302415; called by muse, mutect2, varscan2
- ZNF566 | c.666T>G p.T222= | Silent (SNP) | VAF 28/580 reads (5%) | called by muse, mutect2
- ZNF831 | c.822C>T p.A274= | Silent (SNP) | VAF 224/510 reads (44%) | catalogued as COSV64043031; called by muse, mutect2, varscan2
- ZNF91 | c.3441A>G p.S1147= | Silent (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-5435A>C | Intron (SNP) | VAF 19/206 reads (9%) | called by muse, mutect2, varscan2
- AC244258.1 | n.436G>A | RNA (SNP) | VAF 95/200 reads (48%) | called by muse, mutect2, varscan2
- CHST9 | chr18:26915010 T>G | 3'Flank (SNP) | VAF 31/170 reads (18%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*1338T>G | 3'UTR (SNP) | VAF 33/194 reads (17%) | called by muse, mutect2, varscan2
- GPM6B | c.61+9155C>T | Intron (SNP) | VAF 95/179 reads (53%) | catalogued as rs1216360031; called by muse, mutect2, varscan2
- LAMP2 | c.*2818T>C | 3'UTR (SNP) | VAF 141/141 reads (100%) | catalogued as COSV52352034; called by muse, mutect2, varscan2
- UMOD | c.-121T>A | 5'UTR (SNP) | VAF 35/314 reads (11%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26668175 G>A | 5'Flank (SNP) | VAF 134/262 reads (51%) | catalogued as rs928160133; called by muse, varscan2
